Somatic mutation profile of tumor specimen C3L-01834-02 (aliquot CPT0104220010) from CPTAC case C3L-01834, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,846 days).
Specimen C3L-01834-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d6994e9-b474-4117-a087-7f3cf13d0d92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01834-31 (Blood Derived Normal), aliquot CPT0105090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85989ca5-7269-4847-8e66-3e640042a087

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 256/1100 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- EGFR | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 228/1651 reads (14%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51765787; called by muse, mutect2, varscan2
- ANK1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV55883008; called by muse, mutect2
- COL6A3 | c.5908C>T p.R1970C | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs886042371, CM1413881, COSV55079884; ClinVar: uncertain significance; called by muse, mutect2
- GOLGA8Q | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs747076622; called by muse, mutect2
- MAGEB18 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100305660, COSV57463393; called by muse, mutect2
- MUC4 | c.8687C>T p.P2896L | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs1430709137, COSV57811178; called by muse, mutect2
- PPP1R3A | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 12/194 reads (6%) | catalogued as rs753345410, COSV52878806; called by muse, mutect2
- ZC3H13 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 9/243 reads (4%) | catalogued as rs1307303458; called by muse, mutect2
- CRYBG3 | c.2659C>T p.Q887* | Nonsense Mutation (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- GPRASP1 | c.2097G>T p.E699D | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- HCN1 | c.2304C>A p.H768Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); called by muse, mutect2
- MINPP1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NRK | c.2659A>G p.T887A | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- OR14C36 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPR | c.4739A>C p.E1580A | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2
- TTN | c.75200T>C p.I25067T (on ENST00000591111; = p.I17643T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | PolyPhen benign (0.049); called by muse, mutect2
- HECW1 | c.2058G>A p.S686= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs775565051, COSV67826461; called by muse, mutect2
- HYDIN | c.13077C>T p.L4359= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs1458871526, COSV66639159; called by muse, mutect2
- KCND2 | c.282C>T p.H94= | Silent (SNP) | VAF 20/399 reads (5%) | called by muse, mutect2
- KLHL34 | c.1350G>A p.R450= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- ZNF285 | c.1494T>C p.Y498= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- ZNF845 | c.226A>C p.R76= | Silent (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- SPTAN1 | c.6692+108G>C | Intron (SNP) | VAF 9/223 reads (4%) | called by muse, mutect2
